Gene-level copy-number profile of tumor specimen TCGA-3C-AALJ-01A from TCGA case TCGA-3C-AALJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.6 years (22,848 days).
Specimen TCGA-3C-AALJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6cb7dc53-ea35-431b-9bd9-4f13f5ec40fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3C-AALJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/55187f9c-16ca-45f2-8278-1a9de52711a0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 467; copy number 2: 6,066; copy number 3: 17,392; copy number 4: 22,949; copy number 5: 9,269; copy number 6: 500; copy number 7: 191; copy number 8: 1,374; copy number 9: 565; copy number 10: 378; copy number 11: 76; copy number 12: 73; copy number 13: 90; copy number 15: 19; copy number 16: 24; copy number 17: 13; copy number 18: 14; copy number 19: 50; copy number 20: 13; copy number 21: 50; copy number 22: 8; copy number 23: 9; copy number 24: 143; copy number 25: 24; copy number 30: 43; copy number 43: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3C-AALJ-01A-31D-A41E-01): tumor purity 0.53, ploidy 3.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,600 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:100,208,254–100,426,107, 6 genes, copy number 10: LINC01104, LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2.
- chr6:51,385,282–52,840,843, 29 genes, copy number 9: AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1, PKHD1, RN7SL580P, MIR206, LINCMD1, MIR133B, IL17A, IL17F, SLC25A20P1, MCM3, PAQR8, EFHC1, TRAM2, TRAM2-AS1, AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5.
- chr8:1,246,789–1,622,417, 6 genes, copy number 10: AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1.
- chr8:2,873,525–2,926,689, 2 genes, copy number 9: AC115485.1, AC023296.1.
- chr8:3,373,353–3,426,587, 2 genes, copy number 9: AC026991.1, AC026991.2.
- chr8:36,378,069–39,284,917, 75 genes, copy number 13–43 (within-gene range 2–43) (broad region; genes not listed).
- chr8:61,264,624–61,714,859, 6 genes, copy number 9–10 (within-gene range 2–10): AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470.
- chr8:63,136,223–68,819,023, 84 genes, copy number 12–25 (within-gene range 4–25) (broad region; genes not listed).
- chr8:68,695,643–70,608,416, 34 genes, copy number 10–16 (within-gene range 5–16): RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1.
- chr8:92,144,088–107,648,032, 297 genes, copy number 10–16 (broad region; genes not listed).
- chr10:55,599,042–65,055,003, 85 genes, copy number 9 (broad region; genes not listed).
- chr10:65,570,338–65,880,289, 1 gene, copy number 9 (within-gene range 6–9): LINC01515.
- chr10:67,334,123–70,112,282, 77 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr12:107,809,483–107,912,620, 6 genes, copy number 10 (within-gene range 5–10): AC126177.3, AC126177.5, AC126177.2, AC126177.4, AC126177.6, AC126177.1.
- chr14:20,060,045–20,210,498, 11 genes, copy number 11 (within-gene range 6–11): OR4L1, RNA5SP380, OR4T1P, OR4K17, OR4N5, PSMB7P1, GTF2IP22, OR11G1P, OR11P1P, OR11G2, OR11H5P.
- chr14:36,298,564–38,041,442, 30 genes, copy number 10 (within-gene range 2–10): MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517.
- chr14:48,819,360–48,819,593, 1 gene, copy number 11: AL512360.1.
- chr14:49,373,966–50,416,461, 44 genes, copy number 10 (within-gene range 6–10): ATP5MC2P2, RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1.
- chr14:50,844,625–51,365,557, 14 genes, copy number 10 (within-gene range 2–10): AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2, TRIM9, AL358334.4, AL591770.1, TMX1, SNORA70, Y_RNA, LINC00519, LINC00640.
- chr17:27,351,858–28,196,381, 31 genes, copy number 12–30 (within-gene range 2–30): SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3, AC090287.1, AC090287.2, SNORA70, NLK, Vault, RPS29P22.
- chr17:28,364,356–28,404,049, 1 gene, copy number 9 (within-gene range 2–9): SARM1.
- chr17:28,394,642–28,861,966, 47 genes, copy number 9: SLC46A1, AC015917.2, H3P41, AC015917.1, AC005726.1, RPS7P1, SLC13A2, FOXN1, UNC119, PIGS, ALDOC, AC005726.3, SPAG5, SPAG5-AS1, RSKR, AC005726.4, KIAA0100, AC005726.2, SDF2, RPS12P28, SUPT6H, AC010761.3, PROCA1, RAB34, RPL23A, SNORD42B, AC010761.1, SNORD4A, SNORD42A, SNORD4B, TLCD1, NEK8, AC010761.6, AC010761.2, TRAF4, AC010761.4, AC010761.5, FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732.
- chr17:36,001,419–36,105,621, 7 genes, copy number 9 (within-gene range 2–9): AC244100.3, AC244100.4, CCL23, CCL18, AC243829.4, CCL3, CCL4.
- chr17:47,807,372–49,369,998, 93 genes, copy number 24 (broad region; genes not listed).
- chr17:49,375,380–49,414,901, 4 genes, copy number 24 (within-gene range 2–24): AC091180.4, AC091180.1, PHB, AC091180.3.
- chr17:58,192,726–64,468,643, 223 genes, copy number 9 (broad region; genes not listed).
- chr17:66,835,117–71,871,750, 97 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr20:34,088,309–35,147,336, 37 genes, copy number 9–18: EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A, PIGU, AL118520.1, NCOA6, TP53INP2, AL109824.1, HMGB3P1, GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1.
- chr20:37,693,955–38,337,505, 15 genes, copy number 11–23: CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI.
- chr20:41,024,205–41,317,672, 9 genes, copy number 13 (within-gene range 4–13): RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P.
- chr20:42,968,743–42,971,492, 1 gene, copy number 15: PTPRT-AS1.
- chr20:50,479,767–50,585,241, 2 genes, copy number 15 (within-gene range 7–15): COX6CP2, PTPN1.
- chr20:51,596,514–52,699,472, 15 genes, copy number 13: ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1.
- chr20:53,453,058–56,269,231, 28 genes, copy number 13–23: AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2.
- chr20:56,730,397–60,083,872, 83 genes, copy number 10–30 (broad region; genes not listed).
- chr20:61,953,469–62,296,213, 11 genes, copy number 10: TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2.
- chr20:62,938,147–64,313,132, 86 genes, copy number 13–24 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 467. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
